CPTAC case 1488 — Breast (CPTAC-2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Primary site: Breast.
https://portal.gdc.cancer.gov/cases/983709db-c219-472a-876f-ae87c4094778

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Diagnosis record without a diagnosis name: Tissue or organ of origin: Breast, NOS; Age at diagnosis: 50.0 years (18,249 days); Prior malignancy: no.

Biospecimens (2 samples)
- Sample CPT000815: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample CPT000821: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Frozen.
